Somatic mutation profile of tumor specimen TCGA-EM-A3AN-01A (aliquot TCGA-EM-A3AN-01A-11D-A202-08) from TCGA case TCGA-EM-A3AN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.1 years (13,188 days).
Specimen TCGA-EM-A3AN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 584198fa-35d9-437a-81a5-0c793b3a4b7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AN-10A (Blood Derived Normal), aliquot TCGA-EM-A3AN-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29867e3-e7e5-4758-a25b-053f98c2c29f

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD1 | c.5975C>A p.P1992Q (on ENST00000520002; = p.P1991Q on NM_033225.6) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767313238, COSV59363511; called by muse, mutect2, varscan2
- FLACC1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs142397497; called by muse, mutect2, varscan2
- POU2F2 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs757334613, COSV60765725; called by muse, mutect2, varscan2
- SSTR2 | c.674G>T p.C225F | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV59535842; called by muse, mutect2, varscan2
- INTU | c.2002dup p.T668Nfs*3 | Frame Shift Ins (INS) | VAF 36/124 reads (29%) | called by mutect2, pindel, varscan2
